Somatic mutation profile of tumor specimen TCGA-AH-6643-01A (aliquot TCGA-AH-6643-01A-11D-1826-10) from TCGA case TCGA-AH-6643, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.0 years (18,273 days).
Specimen TCGA-AH-6643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a58c447-6f68-4cc3-863d-23079e5d7321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6643-11A (Solid Tissue Normal), aliquot TCGA-AH-6643-11A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a6267f8-e0d5-40f5-bd02-94ae99759e08

The open-access MAF lists 126 somatic variants for this specimen: 89 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 36, Nonsense Mutation 9, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 61/92 reads (66%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 68/93 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1200A>C p.Q400H | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52705186; called by muse, mutect2
- ACTN2 | c.42C>G p.Y14* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV63973444; called by muse, mutect2, varscan2
- ADCY2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs754055904, COSV57864590; called by muse, mutect2, varscan2
- ADGRA3 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV57545265; called by muse, mutect2, varscan2
- ADGRB3 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 115/212 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs376079687; called by muse, varscan2
- ADRB3 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.051); catalogued as rs1289843904, COSV61461650; called by muse, mutect2, varscan2
- AKR1B1 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53646771; called by muse, mutect2, varscan2
- APOBEC3C | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs778502182, COSV100815142, COSV100815193; called by muse, mutect2, varscan2
- ASAH2 | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61482996; called by muse, mutect2, varscan2
- ASXL2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 68/81 reads (84%) | catalogued as COSV55455792; called by muse, mutect2, varscan2
- C1RL | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV56923995; called by muse, mutect2, varscan2
- C3orf20 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as rs745757801, COSV53783609; called by muse, mutect2
- CARD11 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV62754649; called by muse, mutect2, varscan2
- CHAMP1 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV100778772; called by muse, mutect2, varscan2
- DCT | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as rs148575940; called by muse, mutect2, varscan2
- DOCK2 | c.3290T>G p.L1097R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56949249, COSV99909921; called by muse, mutect2, varscan2
- DSPP | c.3569G>T p.S1190I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV99217050; called by muse, mutect2, varscan2
- FAT3 | c.9863C>A p.P3288H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV53091100; called by muse, mutect2
- FGGY | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100364272; called by muse, mutect2, varscan2
- FILIP1 | c.329T>G p.V110G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV99384468; called by muse, mutect2, varscan2
- FLG | c.10063G>C p.V3355L | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV100911413; called by muse, mutect2, varscan2
- FRMPD2 | c.1835A>C p.K612T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59716486; called by muse, mutect2, varscan2
- GIMAP8 | c.1411C>A p.Q471K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV56230533; called by mutect2, varscan2
- GLI4 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs764644820, COSV60681746, COSV60682413; called by muse, mutect2, varscan2
- GPR139 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs144787739, COSV58502184; called by muse, mutect2, varscan2
- GRIN2A | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV58046640; called by mutect2, varscan2
- GRK3 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60794700; called by muse, mutect2, varscan2
- H4C9 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as rs746626210, COSV62889680; called by muse, mutect2, varscan2
- INSRR | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748927042, COSV63871763; called by muse, mutect2, varscan2
- KCND2 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58573842; called by muse, mutect2, varscan2
- KRT3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs370673258; called by muse, mutect2, varscan2
- KRTAP24-1 | c.156A>C p.Q52H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV61089179; called by muse, mutect2
- LHFPL4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55001411; called by muse, mutect2, varscan2
- MAP2 | c.5012A>G p.K1671R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52285419, COSV99557516; called by muse, mutect2, varscan2
- MCHR2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs142259467, COSV56001077; called by muse, mutect2, varscan2
- MEGF8 | c.5441T>G p.L1814R (on ENST00000251268 / NM_001271938.2; = p.L1747R on NM_001410.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52079035; called by mutect2, varscan2
- MGA | c.6898G>C p.D2300H (on ENST00000219905 / NM_001164273.1; = p.D2091H on NM_001080541.2) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV54951067; called by muse, mutect2, varscan2
- MGAT1 | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | PolyPhen benign (0.031); catalogued as rs761737308, COSV57133368; called by mutect2, varscan2
- MUC5B | c.3673G>A p.G1225R | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs763902961, COSV71590870; called by muse, mutect2, varscan2
- MYB | c.1391C>G p.P464R | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV57196996, COSV57202207; called by muse, mutect2, varscan2
- NRP1 | c.1478A>C p.K493T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV55162685; called by muse, mutect2, varscan2
- OPCML | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.866); catalogued as COSV100099862, COSV59434500; called by muse, mutect2, varscan2
- OR4C12 | c.880A>G p.S294G | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV58859675; called by muse, mutect2, varscan2
- OR52I2 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV57044627; called by muse, mutect2, varscan2
- OSBPL6 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV51913540; called by muse, mutect2, varscan2
- OTOGL | c.2500T>G p.L834V (on ENST00000547103; = p.L825V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV72006185; called by muse, mutect2, varscan2
- PABPC5 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV57039714; called by muse, varscan2
- PCDH17 | c.3394T>A p.S1132T | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV100931559; called by muse, mutect2
- PDGFB | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs531185137, COSV58646257; called by muse, mutect2, varscan2
- PEG3 | c.4215A>C p.E1405D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs776446931, COSV55629146; called by muse, mutect2, varscan2
- PLCH1 | c.1301G>A p.S434N (on ENST00000340059 / NM_001130960.2; = p.S446N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs745842023, COSV58191131; called by muse, mutect2, varscan2
- PREX1 | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs763984566, COSV64249684; called by mutect2, varscan2
- PRICKLE2 | c.1273G>A p.V425I (on ENST00000295902; = p.V369I on NM_198859.4) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs568569832, COSV55764452; called by muse, mutect2, varscan2
- PTPRT | c.3830A>G p.E1277G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100625202, COSV61959394, COSV61962998; called by muse, mutect2, varscan2
- RELA | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs1159602684, COSV58014194; called by muse, mutect2, varscan2
- RNF6 | c.1258A>T p.R420* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV60418175; called by muse, mutect2, varscan2
- RORC | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204625530, COSV59092219; called by muse, mutect2, varscan2
- SACS | c.633A>C p.Q211H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.246); catalogued as COSV101207358; called by muse, mutect2
- SIGLEC5 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55778419; called by muse, mutect2, varscan2
- SLCO6A1 | c.627A>C p.E209D | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101134216; called by muse, mutect2
- SMARCA1 | c.2351C>G p.P784R | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV64411324; called by muse, mutect2, varscan2
- SPART | c.1952A>C p.K651T | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV62087092; called by muse, mutect2
- SPN | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs968049985, COSV64070098; called by muse, mutect2, varscan2
- ST8SIA4 | c.105A>C p.Q35H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | PolyPhen benign (0.084); catalogued as COSV99185195; called by muse, mutect2
- STX5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs542193132, COSV53678619; called by muse, mutect2, varscan2
- TAB2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs747627781, COSV53851614; called by muse, mutect2, varscan2
- TAS2R5 | c.91A>C p.S31R | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV56094615; called by muse, mutect2, varscan2
- TAS2R50 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV67853927; called by muse, mutect2
- TMPRSS9 | c.1334G>C p.G445A (on ENST00000648592; = p.G411A on NM_182973.2) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100211265; called by muse, mutect2, varscan2
- TRAFD1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201271111, COSV57503782; called by muse, mutect2, varscan2
- TTN | c.70958A>C p.E23653A (on ENST00000591111; = p.E16229A on NM_003319.4) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | PolyPhen benign (0.23); catalogued as COSV59955141; called by muse, mutect2
- TTN | c.10167C>A p.F3389L (on ENST00000591111; = p.F3343L on NM_003319.4) | Missense Mutation (SNP) | VAF 41/153 reads (27%) | PolyPhen benign (0.36); catalogued as COSV59955154, COSV60197915; called by muse, mutect2, varscan2
- UBA2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.508); catalogued as COSV55827738, COSV99875811; called by muse, mutect2, varscan2
- VN1R4 | c.593del p.V198Afs*42 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as COSV60804802; called by mutect2, varscan2
- WDR49 | c.1361T>G p.L454R (on ENST00000308378 / NM_001366158.1; = p.L795R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57705031; called by mutect2, varscan2
- WWC3 | c.3074C>A p.A1025D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66502152; called by muse, mutect2, varscan2
- XAB2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs759759087, COSV50331906; called by muse, mutect2
- ZDBF2 | c.3598A>C p.S1200R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV65623359; called by muse, mutect2
- ZMYND8 | c.3259C>T p.Q1087* (on ENST00000311275 / NM_001363741.2; = p.Q1061* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV53684729; called by muse, mutect2, varscan2
- ATP8B1 | c.3528_3531+6del p.X1176_splice | Splice Site (DEL) | VAF 20/37 reads (54%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.2521A>G p.R841G | Missense Mutation (SNP) | VAF 19/406 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- ELF3 | c.868dup p.E290Gfs*11 | Frame Shift Ins (INS) | VAF 80/339 reads (24%) | called by mutect2, pindel, varscan2
- FSD1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PRAMEF19 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STX1A | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ACTR6 | c.1104G>A p.E368= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as COSV51841434; called by muse, mutect2, varscan2
- ADCK5 | c.1665C>T p.T555= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs1185147918, COSV58232817; called by muse, mutect2, varscan2
- ASAH2 | c.174C>A p.T58= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs374685598; called by muse, mutect2, varscan2
- ASS1 | c.534G>A p.P178= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs113818350; called by muse, mutect2, varscan2
- BICRA | c.33C>T p.D11= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1201905676, COSV67604261; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3417G>C p.L1139= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as COSV63244484; called by muse, mutect2, varscan2
- BMPR1B | c.675C>T p.G225= | Silent (SNP) | VAF 57/84 reads (68%) | catalogued as COSV52775884; called by muse, mutect2, varscan2
- BRI3 | c.369C>T p.T123= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV50054993, COSV50056662; called by muse, mutect2, varscan2
- CALHM2 | c.183C>T p.I61= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs767823366, COSV53294773; called by muse, mutect2, varscan2
- CAPN15 | c.2514G>A p.S838= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs369292549; called by muse, mutect2, varscan2
- CCDC38 | c.309C>T p.S103= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs752303324, COSV60182600; called by muse, mutect2, varscan2
- CD79B | c.15G>A p.A5= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs199930415, COSV50076472; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.6939C>G p.L2313= (on ENST00000520002; = p.L2312= on NM_033225.6) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100146458; called by muse, varscan2
- DDX18 | c.876T>C p.S292= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV54305893; called by muse, mutect2, varscan2
- DIAPH3 | c.2904G>T p.S968= (on ENST00000400324 / NM_001042517.2; = p.S705= on NM_030932.3) | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as COSV57366938, COSV57370587; called by muse, mutect2, varscan2
- FAM126A | c.924T>G p.T308= | Silent (SNP) | VAF 30/302 reads (10%) | catalogued as COSV69471398; called by muse, mutect2, varscan2
- FNDC1 | c.4212C>T p.D1404= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs368545994; called by muse, mutect2, varscan2
- HUS1B | c.27C>T p.G9= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs769694715, COSV57862848; called by muse, mutect2, varscan2
- KIAA1549L | c.5412G>A p.S1804= (on ENST00000321505; = p.S2101= on NM_012194.3) | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as rs749737275, COSV58584626; called by muse, mutect2, varscan2
- KNSTRN | c.300G>C p.P100= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV51104131; called by mutect2, varscan2
- LRRC7 | c.1098A>T p.A366= (on ENST00000651989 / NM_001370785.2; = p.A333= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99225824; called by muse, mutect2, varscan2
- LTB4R2 | c.1113C>T p.R371= (on ENST00000528054; = p.R340= on NM_019839.5) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV51864787; called by muse, mutect2, varscan2
- MMP17 | c.1611C>T p.D537= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs762027563, COSV62178767; called by muse, mutect2, varscan2
- MPEG1 | c.1587C>T p.G529= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs201332555, COSV57089348, COSV99914890; called by muse, mutect2, varscan2
- MUC16 | c.12882C>T p.S4294= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs370292934, COSV67454705; called by muse, mutect2, varscan2
- MUC16 | c.4383G>T p.L1461= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV67454710; called by muse, mutect2, varscan2
- MYH1 | c.2553G>A p.K851= | Silent (SNP) | VAF 72/98 reads (73%) | catalogued as COSV56845654; called by muse, mutect2, varscan2
- PCDHA9 | c.1542C>T p.S514= | Silent (SNP) | VAF 99/115 reads (86%) | catalogued as rs782497568, COSV65324672; called by muse, mutect2, varscan2
- PMS2 | c.1780T>C p.L594= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV56220556; called by muse, mutect2, varscan2
- POTEE | c.474C>T p.I158= | Silent (SNP) | VAF 311/875 reads (36%) | catalogued as rs142484775, COSV58227108; called by muse, varscan2
- PRSS55 | c.765C>A p.V255= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV60807977; called by muse, mutect2, varscan2
- PTCH1 | c.687T>C p.I229= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV59467918; called by muse, mutect2, varscan2
- QRICH2 | c.1575C>T p.V525= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53152042; called by muse, mutect2, varscan2
- SLC49A3 | c.666G>A p.P222= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs771658038, COSV59139817; called by muse, mutect2, varscan2
- TMC3 | c.2748C>T p.D916= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1397656767, COSV63922604; called by muse, mutect2, varscan2
- TMEM132B | c.1941G>A p.T647= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs1417211423, COSV54748637; called by muse, mutect2, varscan2
- PRDM15 | c.-191A>C | 5'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as COSV54150507; called by mutect2, varscan2
